Somatic mutation profile of tumor specimen C3N-00573-04 (aliquot CPT0069000006) from CPTAC case C3N-00573, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.3 years (22,407 days).
Specimen C3N-00573-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adcd46a9-14e6-4db8-86e5-e653d95e38c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00573-71 (Blood Derived Normal), aliquot CPT0069090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a08fbea5-8ade-41db-b91c-7183068cdbe9

The open-access MAF lists 71 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Intron 8, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 3, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 107/345 reads (31%) | hotspot (GDC flag); catalogued as rs119103277, CM951277, CM995326, HX971376, COSV56543204, COSV56545932, COSV56566114; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH24 | c.1517A>T p.Q506L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV57464269; called by muse, mutect2, varscan2
- CSMD3 | c.4222C>A p.P1408T (on ENST00000297405 / NM_001363185.1; = p.P1304T on NM_052900.3) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52140148; called by muse, mutect2, varscan2
- EVI2B | c.561T>A p.D187E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58364161; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1280G>T p.C427F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs745838057; called by mutect2, varscan2
- FZD6 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs541992719, COSV62471649; called by muse, mutect2, varscan2
- IKZF1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1446212014, COSV58783463, COSV58786626; called by muse, mutect2, varscan2
- ISLR2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403938121; called by muse, mutect2, varscan2
- MGAT3 | c.1434C>G p.S478R | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV57866855; called by muse, mutect2, varscan2
- MUC5AC | c.15280G>A p.V5094M | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1486891884; called by muse, mutect2, varscan2
- P3H1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254912506; called by muse, mutect2, varscan2
- RAB4A | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1439238668; called by muse, mutect2, varscan2
- VDAC2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1405544782; called by muse, mutect2, varscan2
- ZPBP2 | c.860G>A p.R287H (on ENST00000348931 / NM_199321.3; = p.R265H on NM_198844.3) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs139706909; called by muse, varscan2
- AKAP13 | c.7001C>A p.T2334N (on ENST00000394518 / NM_007200.5; = p.T2338N on NM_006738.6) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AP2M1 | c.989_990del p.T330Kfs*41 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | called by pindel, varscan2
- ARID2 | c.1226dup p.L409Ffs*3 | Frame Shift Ins (INS) | VAF 31/184 reads (17%) | called by mutect2, pindel, varscan2
- CCDC173 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPE | c.1169A>T p.N390I | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- DCTN4 | c.371del p.A124Efs*5 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel
- DHX15 | c.2101-3C>A | Splice Region (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- DMTF1 | c.2022del p.T675Lfs*4 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- DNAI1 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 131/555 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EBF1 | c.1419C>A p.S473R | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FN3K | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 93/384 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GTF3C1 | c.5201A>T p.Y1734F | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6B | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAGI3 | c.3946A>G p.I1316V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCT1 | c.386_391delinsC p.S129Tfs*2 | Frame Shift Del (DEL) | VAF 34/187 reads (18%) | called by pindel, varscan2*
- NAT10 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPB11 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 81/521 reads (16%) | called by muse, mutect2, varscan2
- PAK3 | c.862A>G p.K288E (on ENST00000262836 / NM_001324328.2; = p.K273E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- PREX2 | c.1793C>A p.S598Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- R3HCC1L | c.617G>C p.R206T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RAB36 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN9A | c.4661T>G p.F1554C (on ENST00000303354; = p.F1543C on NM_002977.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHD | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SIGIRR | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLFN14 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- SOGA1 | c.3314dup p.E1106Gfs*36 | Frame Shift Ins (INS) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- SUSD6 | c.439A>T p.K147* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- TAF1L | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TMEM60 | c.181dup p.C61Lfs*2 | Frame Shift Ins (INS) | VAF 26/101 reads (26%) | called by mutect2, pindel, varscan2
- UBR1 | c.5071_5080del p.Y1691Nfs*9 | Frame Shift Del (DEL) | VAF 58/390 reads (15%) | called by mutect2, pindel, varscan2
- UBR1 | c.3403G>T p.E1135* | Nonsense Mutation (SNP) | VAF 73/356 reads (21%) | called by muse, mutect2, varscan2
- ZBTB10 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF236 | c.4152T>A p.N1384K | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AZIN1 | c.522G>A p.L174= | Silent (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- CACNA1B | c.5196C>G p.V1732= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV53123143; called by muse, mutect2, varscan2
- CPE | c.1167G>A p.A389= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as COSV101291754, COSV68580563; called by muse, mutect2
- GFY | c.744C>G p.T248= | Silent (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- KHK | c.705T>C p.P235= | Silent (SNP) | VAF 51/263 reads (19%) | called by muse, mutect2, varscan2
- MBLAC1 | c.489G>A p.V163= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs755430950; called by muse, mutect2, varscan2
- MMP20 | c.39C>A p.L13= | Silent (SNP) | VAF 23/466 reads (5%) | catalogued as COSV52775686; called by muse, mutect2
- NDFIP2 | c.897T>C p.F299= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- PTPRF | c.2724C>T p.I908= | Silent (SNP) | VAF 79/407 reads (19%) | called by muse, mutect2, varscan2
- RNF43 | c.2202C>A p.P734= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- SLC30A1 | c.1140C>T p.S380= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as rs778612093, COSV65361153; called by muse, mutect2, varscan2
- SMG5 | c.1029T>C p.Y343= | Silent (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- USH1G | c.915C>A p.S305= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV58883666; called by muse, mutect2, varscan2
- ZNF99 | c.1407A>G p.R469= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV68054733; called by muse, varscan2
- ADAM23 | c.*32C>T | 3'UTR (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- CSTL1 | c.-1C>G | 5'UTR (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2
- GABRE | c.57-904A>C | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- LAMA4 | c.2173+57A>G | Intron (SNP) | VAF 64/221 reads (29%) | called by muse, mutect2, varscan2
- PTPRO | c.2712-19_2712-18insG | Intron (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- PXN | c.831+1996T>A | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- RPL14 | c.3+157G>A | Intron (SNP) | VAF 37/107 reads (35%) | catalogued as rs1246746835; called by muse, mutect2, varscan2
- RUNX1T1 | c.-86+4471G>C | Intron (SNP) | VAF 42/212 reads (20%) | catalogued as rs1403667692; called by muse, mutect2, varscan2
- SYT7 | c.215+5340C>T | Intron (SNP) | VAF 48/229 reads (21%) | catalogued as COSV55654681; called by muse, mutect2, varscan2
- SYTL2 | c.1459+253G>A | Intron (SNP) | VAF 22/92 reads (24%) | catalogued as rs1218714422; called by muse, mutect2, varscan2
